Surgical pathology report (de-identified scan), TCGA case TCGA-ZP-A9CV, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Medical College of Wisconsin, specimen TCGA-ZP-A9CV-01A (Primary Tumor).

[page 1 of 3]
Results History

SURG PATH FINAL REPORT

Entry Information

Entry Date and Time

Lab Status
Final result

Entered by

Component Results

Component

SURG PATH FINAL REPORT

Accession #:

Specimen:

- A. Gallbladder
- B. HCC segment 5
- C. Liver bx junction 2/3

Clinical Notes:

Liver lesions, gallstones. Fresh tissue from specimen B
saved for tissue bank.

Diagnosis:

- A. Gallbladder:
- Chronic cholecystitis and cholelithiasis.
- B. HCC segment 5:
- Well-differentiated hepatocellular carcinoma with surgical margins free of tumor.
- AJCC staging: pT1 pNX pMX.
- See Synoptic Report for additional information.
- C. Liver biopsy junction 2/3:
- Micronodular cirrhosis with severe macrovesicular steatosis.
- Siderosis 2/4.

(Electronically signed by)

Verified:

Tumor Characteristics:

B: Liver, Resection (AJCC 7th Ed., 2010)

MACROSCOPIC

SPECIMEN TYPE:

Segment 5

FOCALITY

TUMOR SIZE:

Greatest dimension: 2.0 cm

Additional dimensions: 2.0 x 1.5 cm

MICROSCOPIC

ICD-O-3

Carcinoma, hepatocellular
NOS 8170/3

Site: Liver C22.0
JW 3/3/14

[page 2 of 3]
[REDACTED]

HISTOLOGIC TYPE:
Hepatocellular carcinoma
HISTOLOGIC GRADE:
GI: Well differentiated
PRIMARY TUMOR (pT):
pT1: Solitary tumor without vascular invasion
REGIONAL LYMPH NODES (pN):

Accession #:

pNX: Regional lymph nodes cannot be assessed
AJCC STAGING (pTNM):
pT1 pNX pMX
MARGINS:
Parenchymal margin uninvolved by invasive carcinoma
Specify margin: 0.5 cm
LYMPH-VASCULAR INVASION:
Not identified
ADDITIONAL PATHOLOGIC FINDINGS:
Cirrhosis (specify type): Micronodular

Gross:

A. The specimen is labeled "gallbladder." Received in
is a 9.0 x 5.5 x 1.3 cm in diameter gallbladder.
Adjacent to the cystic duct is a 0.8 cm in greatest
dimension pink-tan lymph node candidate. The mucosa is
velvety and orange-tan. The wall thickness is 0.1 cm.
Present within the gallbladder lumen are two ovoid smooth
black-green stones, 1.8 and 2.5 cm in greatest dimension.
The wall thickness ranges from 0.2 to 1.0 cm.
Representative sections, including the cystic duct margin
and possible lymph node are submitted in cassette A.

B. The specimen is labeled "HCC segment 5." Received fresh
in is a 26.8 gm, 4.6 x 3.7 x 2.5 cm portion of
liver. Numerous sutures and staples are present. The
capsule is smooth and purple-pink. The resection margin is
marked with black ink. The specimen is previously incised.
Further sectioning reveals a 2.0 x 2.0 x 1.5 cm well-
circumscribed nodular green-tan lesion which extends to the
hepatic capsule. The lesion is 0.5 cm from the closest
black inked resection surface. The lesion is well-
demarcated from the remaining hepatic parenchyma which is
orange-tan. Representative sections from the well-defined
lesion and unremarkable liver are submitted to
tissue bank. Representative sections are
submitted for permanent as follows:

Cassette Designation:

B1 Well-defined lesion with closest

[REDACTED]

[page 3 of 3]
[REDACTED]

resection margin

B2-3
parenchyma

Well-defined lesion with surrounding

B4-6

Unremarkable parenchyma

C. The specimen is labeled "liver bx, junction 2/3."
Received in Tis-u-Sol are two 0.1 cm in diameter cores of
yellow-tan tissue with lengths of 1.1 and 2.0 cm. The

Accession #:

specimen is submitted in toto in cassette C. Iron,
reticulin and trichrome stains are requested.

Microscopic:

Histological examinations have been performed on specimens
A-C.

A. The mucosa of the gallbladder is intact. The wall of
the gallbladder shows focal areas of fibrosis. There is no
evidence of malignancy.

B. Sections of liver show a well-circumscribed
hepatocellular carcinoma. The tumor is proliferating, and
broad, trabeculated individual cells are polyhedral in shape
with oval, central nuclei. There is no severe dysplasia.
The resection margins are free of tumor. Adjacent liver
uninvolved by the tumor shows marked fatty change and
micronodular cirrhosis.

C. H and E, reticulin and trichrome-stained sections of
liver show a micronodular cirrhosis with a well-developed
micronodular pattern. Regenerative nodules show severe
macrovesicular steatosis, and the liver biopsy shows no
evidence of dysplasia or neoplasia. Iron stain shows 2+
siderosis.

Administrative Notes:

CPT:

No charge codes are associated with this case.

[REDACTED]

Source: NCI Genomic Data Commons file fbb4e44f-aa1a-4cc2-98b0-6353cf5ad6e3 (TCGA-ZP-A9CV.382219F6-24AD-49BD-96D1-FC7A9B2CDFDB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).